Gene-level copy-number profile of tumor specimen TCGA-L5-A8NV-01A from TCGA case TCGA-L5-A8NV, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 75.4 years (27,546 days).
Specimen TCGA-L5-A8NV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.ade44661-1885-4ce5-8287-90f620d6a369.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A8NV-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a4ecb077-77f8-405a-a429-f80f84975ab1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 324; copy number 1: 19,049; copy number 2: 34,025; copy number 3: 5,990; copy number 4: 427.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A8NV-01A-11D-A37B-01): tumor purity 0.41, ploidy 3.13, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 324 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr11:48,880,111–59,479,361, 306 genes (broad region; genes not listed).
- chr11:134,274,245–135,075,908, 16 genes: GLB1L3, AP000859.1, GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.3, AP001999.1, AP001999.2, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 16,628. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
